RC case RC-B6E3 — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4958d332-fc4a-484c-967e-f48dc126feeb

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1944; Vital status: Alive.

Diagnoses (9)
1. Adult T-cell leukemia/lymphoma (HTLV-1 positive) (includes all variants) (the primary disease): ICD-O-3 morphology code: 9827/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 68.1 years (24,869 days); Year of diagnosis: 2012; Method of diagnosis: Blood Draw; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): Low-Intermediate Risk; Sites of involvement: Peripheral blood.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: DA-EPOCH; Days to treatment start: 53 days; Days to treatment end: 163 days; Number of cycles: 6; Treatment outcome: Complete Response; Reason treatment ended: Other; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Methotrexate; Initial disease status: Initial Diagnosis; Days to treatment start: 53 days; Days to treatment end: 163 days; Number of cycles: 6; Treatment outcome: Complete Response; Reason treatment ended: Other; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Days to treatment start: 199 days; Treatment outcome: Complete Response; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Anti-CD25-PBD Antibody-drug Conjugate ADCT-301; Initial disease status: Progressive Disease; Days to treatment start: 2,645 days (7.2 years); Days to treatment end: 2,739 days (7.5 years); Treatment outcome: Treatment Stopped Due to Toxicity; Reason treatment ended: Adverse Event; Clinical trial indicator: Yes; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Mogamulizumab; Initial disease status: Progressive Disease; Days to treatment start: 2,746 days (7.5 years); Days to treatment end: 2,788 days (7.6 years); Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lenalidomide; Initial disease status: Progressive Disease; Days to treatment start: 2,838 days (7.8 years); Days to treatment end: 2,862 days (7.8 years); Treatment outcome: Treatment Stopped Due to Toxicity; Reason treatment ended: Adverse Event; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Brentuximab Vedotin; Initial disease status: Progressive Disease; Days to treatment start: 2,956 days (8.1 years); Days to treatment end: 3,313 days (9.1 years); Number of cycles: 14; Treatment outcome: Progressive Disease; Reason treatment ended: Adverse Event; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Other; Initial disease status: Progressive Disease; Days to treatment start: 3,346 days (9.2 years); Days to treatment end: 3,346 days (9.2 years); Treatment outcome: Progressive Disease; Reason treatment ended: Course of Therapy Completed; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease; Days to treatment start: 3,429 days (9.4 years); Days to treatment end: 3,440 days (9.4 years); Reason treatment ended: Course of Therapy Completed; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Clinical Trial Agent; Initial disease status: Progressive Disease; Days to treatment start: 3,479 days (9.5 years); Treatment outcome: Treatment Ongoing; Clinical trial indicator: Yes; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Days to treatment start: 3,704 days (10.1 years); Days to treatment end: 3,744 days (10.3 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 3,758 days (10.3 years); Days to treatment end: 3,779 days (10.3 years); Treatment dose: 9,000 cGy; Treatment outcome: Progressive Disease; Number of fractions: 30; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Etoposide; Days to treatment start: 3,761 days (10.3 years); Days to treatment end: 3,807 days (10.4 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine + Pegylated Liposomal Doxorubicin Hydrochloride; Days to treatment start: 3,824 days (10.5 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Recurrence (histology not recorded by GDC). Age at diagnosis: 75.1 years (27,438 days); Days to diagnosis: 2,569 days (7.0 years).
3. Synchronous primary of the liver (histology not recorded by GDC). Age at diagnosis: 75.1 years (27,440 days); Year of diagnosis: 2019; Days to diagnosis: 2,571 days (7.0 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 2,603 days (7.1 years); Treatment anatomic sites: Other.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Progression (histology not recorded by GDC). Age at diagnosis: 75.8 years (27,675 days); Days to diagnosis: 2,806 days (7.7 years).
5. Progression (histology not recorded by GDC). Age at diagnosis: 77.2 years (28,207 days); Days to diagnosis: 3,338 days (9.1 years).
6. Recurrence (histology not recorded by GDC). Age at diagnosis: 77.4 years (28,272 days); Days to diagnosis: 3,403 days (9.3 years).
7. Progression of the connective, subcutaneous and other soft tissues (histology not recorded by GDC). Age at diagnosis: 78.1 years (28,515 days); Days to diagnosis: 3,646 days (10.0 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Progressive Disease.
8. Progression (histology not recorded by GDC). Age at diagnosis: 78.3 years (28,609 days); Days to diagnosis: 3,740 days (10.2 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Progressive Disease.
9. Progression (histology not recorded by GDC). Age at diagnosis: 78.5 years (28,685 days); Days to diagnosis: 3,816 days (10.4 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Progressive Disease.

Follow-up (8 entries)
- Day 2,569 (recurrence): Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 2,569 days (7.0 years).
- Day 2,806 (progression): Disease response: With Tumor; Progression or recurrence: Yes; Days to progression: 2,806 days (7.7 years).
- Day 3,338 (progression): Disease response: With Tumor; Progression or recurrence: Yes; Days to progression: 3,338 days (9.1 years).
- Day 3,403 (recurrence): Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 3,403 days (9.3 years).
- Day 3,646 (progression): Disease response: Partial Response; Progression or recurrence: Yes; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues, NOS; Days to progression: 3,646 days (10.0 years).
- Day 3,740 (progression): Progression or recurrence: Yes; Days to progression: 3,740 days (10.2 years).
- Day 3,816 (progression): Progression or recurrence: Yes; Days to progression: 3,816 days (10.4 years).
- Days to follow up: 3,922 days (10.7 years); Karnofsky performance status: 80; ECOG performance status: 1.

Molecular and laboratory tests
- Lactate Dehydrogenase 244 U/L [Blood test normal range upper: 225].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Hepatitis B Infection.
- Timepoint category: Initial Diagnosis; Weight: 98 kg; Height: 168 cm; BMI: 34.7.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample RC-B6E3-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B6E3-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
